Somatic mutation profile of tumor specimen MP2PRT-PASSHE-TMP1-A (aliquot MP2PRT-PASSHE-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASSHE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,695 days).
Specimen MP2PRT-PASSHE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8cd91a8-c9d3-4a32-ad26-bfbc55fc264e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASSHE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASSHE-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62d64928-2a62-41f6-9fc8-4776675b61ad

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB1 | c.4168C>T p.R1390* | Nonsense Mutation (SNP) | VAF 68/327 reads (21%) | catalogued as rs763324776, CM130803, COSV66337060; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CCDC9B | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 62/295 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761209673, COSV101233539; called by muse, mutect2, varscan2
- FLNC | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 73/249 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773023988; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC5D | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs1334662855, COSV54772780, COSV54774766; called by mutect2, varscan2
- EPOR | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 73/409 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ITGA1 | c.3412G>C p.G1138R | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LRCH2 | c.423A>T p.L141F | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC4A4 | c.1106G>C p.G369A (on ENST00000264485 / NM_001098484.3; = p.G325A on NM_003759.4) | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2
- FZD3 | c.258T>C p.A86= | Silent (SNP) | VAF 77/353 reads (22%) | catalogued as rs1334084861; called by muse, mutect2, varscan2
- SVEP1 | c.6714C>T p.V2238= | Silent (SNP) | VAF 50/282 reads (18%) | catalogued as rs775187334, COSV52835801; called by muse, mutect2, varscan2
- IGLL5 | chr22:22899618 del TGT | 3'Flank (DEL) | VAF 38/253 reads (15%) | called by pindel*, varscan2
